Somatic mutation profile of tumor specimen TCGA-IN-A6RO-01A (aliquot TCGA-IN-A6RO-01A-12D-A33T-08) from TCGA case TCGA-IN-A6RO, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.6 years (25,789 days).
Specimen TCGA-IN-A6RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3b5dc01-a1a5-4bbd-8b9c-93b667a7826b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A6RO-10A (Blood Derived Normal), aliquot TCGA-IN-A6RO-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a216b125-3bcb-42af-841f-7543dad90846

The open-access MAF lists 305 somatic variants for this specimen: 238 protein-altering or splice-affecting, 62 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 62, Nonsense Mutation 15, Frame Shift Del 8, Splice Site 5, In Frame Del 2, RNA 2, Frame Shift Ins 2, Splice Region 1, Intron 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB7 | c.1423G>A p.D475N (on ENST00000373394 / NM_001271696.3; = p.D476N on NM_004299.6) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99504036, COSV99504325; called by muse, mutect2, varscan2
- ACAN | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs148018909, COSV100717370, COSV61358645; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1975A>G p.T659A | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV99717539; called by muse, mutect2
- ADCY3 | c.2305G>A p.V769M | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV99567864; called by muse, mutect2, varscan2
- ADGRL3 | c.1295T>A p.I432N (on ENST00000506720 / NM_001322402.2; = p.I364N on NM_015236.6) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101546920; called by muse, mutect2, varscan2
- AGPS | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV51562680; called by muse, mutect2, varscan2
- AGT | c.1375C>G p.P459A | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100794243; called by muse, mutect2, varscan2
- AKAP9 | c.7465C>G p.L2489V (on ENST00000359028; = p.L2465V on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100662085; called by muse, mutect2, varscan2
- AMELX | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs760321133, CD023227, COSV61634124; called by muse, mutect2, varscan2
- AMPH | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs960856901, COSV100341316; called by muse, mutect2, varscan2
- ANKLE2 | c.1178A>C p.Q393P | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100513986; called by muse, mutect2
- APBA2 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs755550991, COSV101382160, COSV68790033; called by muse, mutect2, varscan2
- AQR | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV99333462; called by muse, mutect2, varscan2
- ARID4B | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs773274229, COSV99935200; called by muse, mutect2, varscan2
- ARVCF | c.1441A>G p.I481V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV99599025; called by muse, mutect2, varscan2
- ATP10A | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100790992; called by muse, mutect2, varscan2
- BEND7 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100346483; called by muse, mutect2, varscan2
- BPNT1 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100435595, COSV100435811; called by muse, mutect2, varscan2
- BRCA2 | c.5803A>G p.N1935D | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV101204010; called by muse, mutect2
- C4orf19 | c.474G>C p.M158I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99448460; called by muse, mutect2, varscan2
- C6 | c.1058T>C p.L353S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs928541183, COSV99666721; called by muse, mutect2, varscan2
- CAP1 | c.1170G>C p.E390D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as rs1450513855, COSV100471971; called by muse, mutect2, varscan2
- CATSPER3 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs780475409, COSV50945479, COSV50949049; called by muse, mutect2, varscan2
- CCAR1 | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV99770756; called by muse, mutect2, varscan2
- CCDC185 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as rs148332886, COSV100838765; called by muse, mutect2
- CCDC85A | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs778914418, COSV101339409; called by muse, mutect2, varscan2
- CDH15 | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV57023433; called by muse, mutect2, varscan2
- CDH16 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100233730; called by muse, mutect2, varscan2
- CDKL4 | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101115161; called by muse, mutect2, varscan2
- CERCAM | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.727); catalogued as rs778783636, COSV65710599; called by muse, mutect2, varscan2
- CFAP61 | c.1778C>A p.P593Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99843794; called by muse, mutect2
- CFH | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.753); catalogued as rs1332043837, COSV100809094; called by muse, mutect2, varscan2
- CGNL1 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777197872, COSV99847704; called by mutect2, varscan2
- CHRM2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV100280895, COSV57785775; called by muse, mutect2, varscan2
- CLEC2B | c.138C>G p.C46W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946921, COSV99946960; called by muse, mutect2, varscan2
- CNPPD1 | c.1202C>A p.A401D | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.298); catalogued as COSV99840946; called by muse, mutect2, varscan2
- CNTNAP5 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV70484487; called by muse, mutect2, varscan2
- COL1A2 | c.2538G>T p.K846N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51964346, COSV99798911; called by muse, mutect2, varscan2
- COL26A1 | c.368G>T p.G123V (on ENST00000313669 / NM_001278563.3; = p.G121V on NM_133457.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100561557; called by muse, mutect2
- COL5A3 | c.2681G>A p.R894Q | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773833887, COSV53412673, COSV99318387; called by muse, mutect2, varscan2
- CR1L | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99686956; called by muse, mutect2, varscan2
- CSMD2 | c.9913A>T p.K3305* | Nonsense Mutation (SNP) | VAF 101/135 reads (75%) | catalogued as COSV99587228; called by muse, mutect2, varscan2
- CSMD3 | c.7038T>G p.N2346K (on ENST00000297405 / NM_001363185.1; = p.N2242K on NM_052900.3) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV99828124; called by muse, mutect2, varscan2
- CUL9 | c.4727G>A p.R1576Q | Missense Mutation (SNP) | VAF 132/326 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746067860, COSV99335018; called by muse, mutect2, varscan2
- CYP19A1 | c.788G>T p.R263I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99547444; called by muse, mutect2, varscan2
- DCAF12L1 | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV100948147; called by muse, mutect2, varscan2
- DCLK1 | c.473C>G p.S158W | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV55209188; called by muse, mutect2
- DIAPH1 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as rs761387295, COSV99338748; called by muse, mutect2, varscan2
- DLC1 | c.1654G>C p.E552Q (on ENST00000276297 / NM_001348081.2; = p.E115Q on NM_006094.5) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV52313053, COSV99361802; called by muse, mutect2, varscan2
- DNAH10 | c.12743C>G p.T4248R (on ENST00000409039; = p.T4187R on NM_207437.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99435328; called by muse, mutect2, varscan2
- DNAH8 | c.7379C>A p.T2460N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543858; called by muse, mutect2, varscan2
- DNAJB14 | c.534T>A p.C178* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100508333; called by muse, mutect2, varscan2
- DPYSL5 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as rs773526134, COSV56514434; called by muse, mutect2, varscan2
- EPHB6 | c.2621C>A p.A874E | Missense Mutation (SNP) | VAF 200/429 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140748660, COSV100844183; called by muse, mutect2, varscan2
- FAT3 | c.9903T>A p.Y3301* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99963251; called by muse, varscan2
- FIGN | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100291808; called by muse, mutect2, varscan2
- FOSL2 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99268249; called by muse, mutect2
- FPGT-TNNI3K | c.1940G>C p.S647T | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100435981; called by muse, mutect2
- FRMD4A | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs1486208845, COSV99198422; called by muse, mutect2, varscan2
- FRY | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs768344537, COSV100968908; called by muse, mutect2, varscan2
- FZD4 | c.1595del p.G532Afs*46 | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | catalogued as COSV101536067; called by mutect2, pindel, varscan2
- GJD2 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 11/144 reads (8%) | catalogued as COSV99290610; called by muse, mutect2
- GP5 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100540717; called by muse, mutect2, varscan2
- GRID2 | c.2074C>A p.R692S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV56179444, COSV99938582; called by muse, mutect2, varscan2
- H3C11 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV100137751, COSV58899594; called by muse, mutect2, varscan2
- HAGHL | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV52405908, COSV99284623; called by muse, mutect2, varscan2
- HAND1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746068193, COSV99163957; called by muse, mutect2, varscan2
- HDAC5 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.044); catalogued as COSV99870381; called by muse, mutect2, varscan2
- HECTD1 | c.6047C>G p.S2016* | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | catalogued as COSV101237326, COSV101237352; called by muse, mutect2
- HELQ | c.2723G>A p.G908E | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99787493; called by muse, mutect2, varscan2
- HGF | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); catalogued as rs1032300573, COSV99736017; called by muse, mutect2, varscan2
- HGF | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV99736021; called by muse, mutect2, varscan2
- HLA-B | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs185573735, COSV101317905; called by muse, mutect2, varscan2
- HMCN1 | c.14591A>T p.N4864I | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99625705; called by muse, mutect2, varscan2
- HPGDS | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.189); catalogued as COSV54775769, COSV99755547; called by muse, mutect2, varscan2
- HPS1 | c.1687C>G p.Q563E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100282402; called by muse, mutect2, varscan2
- IGHV1-2 | c.273G>C p.R91S | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs111655461; called by muse, mutect2, varscan2
- INHBA | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs534590694, COSV99637323; called by muse, mutect2, varscan2
- ITGAV | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs771409986, COSV99654443; called by muse, mutect2, varscan2
- KCNK7 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442064; called by muse, mutect2, varscan2
- KCNT1 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs755348603, COSV53713846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDR | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55759554, COSV99816968; called by muse, mutect2, varscan2
- KIAA0232 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370839953; called by muse, mutect2, varscan2
- KIF26A | c.4447G>A p.G1483S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs775132075, COSV59465587; called by muse, mutect2, varscan2
- KL | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 30/667 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV101199039; called by muse, mutect2
- KLF17 | c.1007T>A p.V336E | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100954857; called by muse, mutect2, varscan2
- KRT25 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100379850; called by muse, mutect2, varscan2
- LIG3 | c.2576G>A p.G859D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as rs1318377484, COSV99252305; called by muse, mutect2, varscan2
- LRAT | c.593C>A p.S198* | Nonsense Mutation (SNP) | VAF 55/110 reads (50%) | catalogued as COSV60476368; called by muse, mutect2, varscan2
- LRIT2 | c.1502T>G p.L501R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100258560; called by muse, mutect2, varscan2
- LRP12 | c.1401T>G p.S467R | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99407366; called by muse, mutect2, varscan2
- LRP1B | c.2740A>C p.N914H | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV100796617; called by muse, varscan2
- LRRK2 | c.2209C>G p.Q737E | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100109513; called by muse, mutect2, varscan2
- LY75 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV55101386, COSV99716149; called by muse, mutect2, varscan2
- MAP2K7 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV101209001; called by muse, mutect2, varscan2
- MAP3K5 | c.2826C>G p.S942R | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.261); catalogued as COSV100752592; called by muse, mutect2, varscan2
- MAP3K7 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV65234308; called by muse, mutect2, varscan2
- MCM3AP | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV99386591; called by muse, mutect2, varscan2
- MED18 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV100868916; called by muse, mutect2, varscan2
- MGA | c.5618C>A p.S1873Y (on ENST00000219905 / NM_001164273.1; = p.S1664Y on NM_001080541.2) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV99578953; called by muse, mutect2, varscan2
- MTPAP | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV99553881; called by muse, mutect2, varscan2
- MUC16 | c.7624T>G p.F2542V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV101198770; called by muse, mutect2, varscan2
- MYH3 | c.5190G>T p.K1730N | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99877893; called by muse, mutect2, varscan2
- NBEA | c.8533C>T p.R2845* | Nonsense Mutation (SNP) | VAF 52/415 reads (13%) | catalogued as rs1288199769, COSV59762270; called by muse, mutect2, varscan2
- NDST3 | c.1586T>G p.L529R | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99629907; called by muse, mutect2, varscan2
- NEBL | c.2045A>T p.Q682L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV101009136; called by muse, mutect2, varscan2
- NFATC2 | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs751513686, COSV101043768; called by muse, mutect2, varscan2
- NLRP1 | c.3941C>G p.P1314R (on ENST00000572272 / NM_033004.4; = p.P1270R on NM_014922.5) | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99333301; called by muse, mutect2, varscan2
- NOL4 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 66/82 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV99305521; called by muse, mutect2, varscan2
- NOTCH2 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 98/173 reads (57%) | SIFT tolerated (0.5); PolyPhen benign (0.355); catalogued as COSV99863146; called by muse, mutect2, varscan2
- NRK | c.4468T>G p.F1490V | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV99686947; called by muse, mutect2
- NXPE1 | c.1466G>T p.R489M (on ENST00000424269; = p.R347M on NM_152315.5) | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.3); PolyPhen benign (0.201); catalogued as COSV99320080; called by muse, mutect2, varscan2
- OGFOD2 | c.435C>A p.F145L (on ENST00000228922 / NM_001304833.1; = p.F85L on NM_024623.3) | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99965593; called by muse, mutect2, varscan2
- OR10A2 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs746159207, COSV56300141; called by muse, mutect2, varscan2
- OR2T3 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs965513390, COSV100613141; called by mutect2, varscan2
- OR2T8 | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs1395751162, COSV100178133; called by muse, varscan2
- OR4A16 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs12807769; called by muse, mutect2, varscan2
- OR4C16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV58940520; called by muse, mutect2, varscan2
- OR5H1 | c.714T>G p.F238L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.248); catalogued as COSV100641638, COSV63402105; called by muse, mutect2
- PARP4 | c.4927G>C p.E1643Q | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV101131372; called by muse, mutect2, varscan2
- PAX4 | c.731T>A p.L244Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV100490011; called by muse, mutect2, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PCDH15 | c.5634A>C p.E1878D | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV57330048; called by muse, mutect2, varscan2
- PCDH17 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV64976280; called by muse, mutect2, varscan2
- PCDHA1 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs1216959353, COSV65373796; called by muse, mutect2, varscan2
- PCDHA11 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as rs1554164527, COSV100248662, COSV56547654; called by muse, mutect2, varscan2
- PCLAF | c.127+1G>T p.X43_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100256880; called by muse, mutect2, varscan2
- PCLO | c.11817A>C p.Q3939H | Missense Mutation (SNP) | VAF 149/340 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100428853, COSV61660580, COSV61676960; called by muse, mutect2, varscan2
- PCSK2 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52732700; called by muse, mutect2, varscan2
- PDS5B | c.249C>G p.C83W | Missense Mutation (SNP) | VAF 64/1128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100220668; called by muse, mutect2
- PEAK1 | c.333G>C p.L111F | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV100432625, COSV56944704; called by muse, mutect2, varscan2
- PHLPP2 | c.3617G>A p.R1206Q | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as rs1400230640, COSV62423299; called by muse, mutect2, varscan2
- PIK3CD | c.1880G>T p.C627F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740044; called by muse, mutect2, varscan2
- PON3 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV99672328; called by muse, mutect2, varscan2
- PPP1R16B | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs751756577, COSV55374174; called by muse, mutect2, varscan2
- PREX2 | c.2597A>C p.N866T | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV99905726; called by muse, mutect2, varscan2
- PRICKLE1 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750913400, COSV58209982; called by muse, mutect2, varscan2
- PROKR2 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99449986; called by muse, mutect2
- PRPF40B | c.250G>A p.A84T (on ENST00000380281; = p.A78T on NM_012272.3) | Missense Mutation (SNP) | VAF 115/178 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0.223); catalogued as rs752777680, COSV99979519; called by muse, varscan2
- PSD4 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.026); catalogued as COSV99830901; called by muse, mutect2, varscan2
- PTPN11 | c.1447+2T>A p.X483_splice | Splice Site (SNP) | VAF 43/99 reads (43%) | catalogued as COSV100692290; called by muse, varscan2
- PTPRF | c.4198G>A p.V1400I | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764399239, COSV63445540; called by muse, mutect2, varscan2
- PTPRT | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373191879, COSV61981995; called by muse, mutect2, varscan2
- PTPRZ1 | c.6475C>G p.L2159V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101099760; called by muse, mutect2, varscan2
- RB1 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 97/128 reads (76%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.761); catalogued as rs1270702085, COSV99923707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL2 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV100182117; called by muse, mutect2
- RELN | c.8113A>C p.T2705P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV100632829; called by muse, mutect2, varscan2
- RFXANK | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as rs757517948, COSV57393806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS1 | c.4526G>A p.R1509Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs746144932; called by muse, mutect2
- RINT1 | c.1318A>T p.T440S | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.161); catalogued as COSV99994280; called by muse, mutect2, varscan2
- RNF10 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100378517; called by muse, mutect2, varscan2
- RNF150 | c.1173G>T p.E391D | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60792994; called by muse, mutect2, varscan2
- ROR2 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM004800, COSV100995605; called by muse, mutect2, varscan2
- RPL36A | c.98T>A p.L33Q | Missense Mutation (SNP) | VAF 65/70 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100864956; called by muse, mutect2, varscan2
- RPS6KA2 | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV55823381; called by muse, mutect2, varscan2
- SASS6 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54930493, COSV99078725; called by muse, mutect2, varscan2
- SCARA5 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV100107733; called by muse, mutect2, varscan2
- SCUBE3 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1462578883, COSV99234123; called by muse, mutect2
- SEC14L5 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.631); catalogued as rs955243183, COSV99228654, COSV99229506; called by muse, mutect2, varscan2
- SEPTIN4 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57899961; called by muse, mutect2, varscan2
- SETD1A | c.3545C>G p.P1182R | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as COSV99352605; called by muse, mutect2, varscan2
- SF3A1 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV99305279; called by muse, mutect2, varscan2
- SLA2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as rs556544498, COSV99481187; called by muse, mutect2, varscan2
- SLC10A1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV99384127; called by muse, mutect2, varscan2
- SLC22A18 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV56540115; called by muse, mutect2, varscan2
- SLC39A5 | c.884T>A p.L295H | Missense Mutation (SNP) | VAF 210/321 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs779237706, COSV99907385; called by muse, mutect2, varscan2
- SLC8A1 | c.1417A>T p.K473* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100245109; called by muse, mutect2, varscan2
- SLCO1A2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100261453; called by muse, mutect2
- SLCO1B3 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV99681053; called by muse, mutect2, varscan2
- SMARCB1 | c.63C>A p.D21E | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99303113; called by muse, mutect2, varscan2
- SMCHD1 | c.2218G>C p.G740R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV99860964; called by mutect2, varscan2
- SMIM29 | c.154G>C p.E52Q (on ENST00000394990 / NM_001008704.3; = p.E72Q on NM_178508.5) | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100102799; called by muse, mutect2, varscan2
- SMYD2 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873140; called by muse, mutect2, varscan2
- SNRNP200 | c.4847G>T p.G1616V | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100107336; called by muse, mutect2, varscan2
- SOX7 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778831845, COSV58730315; called by muse, mutect2, varscan2
- SPRY3 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100249239; called by muse, mutect2, varscan2
- SPRYD4 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 114/203 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.134); catalogued as rs772888157, COSV100358241; called by muse, mutect2, varscan2
- SRMS | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751298544, COSV99420374; called by muse, mutect2, varscan2
- SRSF5 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV101275264; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 34/67 reads (51%) | PolyPhen probably damaging (0.99); catalogued as COSV100602491; called by muse, mutect2, varscan2
- ST8SIA6 | c.1145T>A p.L382H | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101112112; called by muse, mutect2, varscan2
- STAG2 | c.3080C>A p.T1027N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); catalogued as COSV54359564; called by muse, mutect2, varscan2
- STARD8 | c.9G>C p.L3F | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99366384; called by muse, mutect2, varscan2
- STIM1 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56159349, COSV56159980; called by muse, mutect2
- STT3A | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101205129; called by muse, mutect2, varscan2
- SUPT3H | c.727-2A>G p.X243_splice (on ENST00000371460 / NM_181356.3; = p.X232_splice on NM_003599.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100176463; called by muse, mutect2, varscan2
- SWAP70 | c.724T>C p.Y242H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100013602; called by muse, mutect2, varscan2
- SYNE2 | c.8082G>C p.W2694C | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100647051; called by muse, mutect2, varscan2
- TAAR2 | c.955T>C p.Y319H (on ENST00000367931 / NM_001033080.1; = p.Y274H on NM_014626.3) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99255562; called by muse, mutect2, varscan2
- TAF1 | c.4318A>G p.N1440D (on ENST00000373790 / NM_138923.4; = p.N1461D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99334912; called by muse, mutect2, varscan2
- TAF4 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1434200996, COSV99433673; called by muse, mutect2, varscan2
- TCTEX1D2 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs1223717866, COSV100308785; called by muse, mutect2, varscan2
- TECRL | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.432); catalogued as COSV101168593; called by muse, mutect2, varscan2
- TECTA | c.4366G>A p.V1456M | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99879045; called by muse, mutect2, varscan2
- TGM5 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs750713894, COSV55009840, COSV55012632; called by muse, mutect2, varscan2
- THRAP3 | c.2623C>A p.P875T | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663262; called by muse, mutect2, varscan2
- TIAM1 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99733649; called by muse, mutect2, varscan2
- TMEM132B | c.2222T>G p.L741R | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT tolerated (0.81); PolyPhen benign (0.325); catalogued as COSV100168883; called by muse, mutect2, varscan2
- TNS3 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs200906390, COSV100235085; called by muse, mutect2, varscan2
- TPBG | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100869755; called by muse, mutect2, varscan2
- TRAPPC9 | c.2105C>T p.S702F | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV101226960; called by muse, mutect2, varscan2
- TRPC4 | c.392T>A p.L131H | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs780570099, COSV100156211; called by muse, mutect2, varscan2
- TTC14 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV99931895; called by muse, mutect2, varscan2
- TTN | c.23572A>T p.K7858* (on ENST00000591111; = p.K6931* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/61 reads (51%) | catalogued as COSV100600205; called by muse, mutect2, varscan2
- TUT4 | c.1002A>G p.E334= | Splice Region (SNP) | VAF 6/22 reads (27%) | catalogued as rs777614259, COSV99931964; called by muse, varscan2
- TYK2 | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99314433; called by muse, mutect2, varscan2
- UBA2 | c.1702A>T p.N568Y | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV55831109; called by muse, mutect2, varscan2
- UBA6 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100451593; called by muse, mutect2, varscan2
- UBR4 | c.3083C>G p.P1028R | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV100920557, COSV100920776, COSV100921418; called by muse, mutect2, varscan2
- USH2A | c.4283C>G p.S1428C | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as COSV100231071; called by muse, mutect2, varscan2
- VIPR2 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100056774; called by muse, mutect2, varscan2
- VPS13B | c.4615C>G p.L1539V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV100661160; called by muse, mutect2, varscan2
- WNT5A | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99224779; called by muse, mutect2, varscan2
- ZNF415 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701347; called by muse, mutect2, varscan2
- ZNF526 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs750582519, COSV100004359; called by muse, mutect2, varscan2
- ZNF570 | c.83G>A p.W28* | Nonsense Mutation (SNP) | VAF 19/289 reads (7%) | catalogued as COSV100356070; called by muse, mutect2
- ZNF675 | c.467T>A p.F156Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100704958; called by muse, mutect2, varscan2
- ZNF677 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV100447823, COSV61721076; called by muse, mutect2, varscan2
- ZNF780B | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99665430; called by muse, mutect2, varscan2
- ZNF835 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV73379615; called by muse, mutect2, varscan2
- ZSCAN4 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100552421; called by muse, mutect2, varscan2
- ATP6V1C2 | c.994_1023del p.F332_H341del (on ENST00000272238 / NM_001039362.2; = p.F286_H295del on NM_144583.4) | In Frame Del (DEL) | VAF 32/89 reads (36%) | called by mutect2, pindel
- CDK12 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 596/7402 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2
- DNAH7 | c.9451dup p.I3151Nfs*16 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- DRG1 | c.1005-7_1007del p.X335_splice | Splice Site (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- FCGBP | c.12547C>T p.H4183Y | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPR179 | c.6589C>T p.Q2197* (on ENST00000621958; = p.Q2196* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- GPR179 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2
- GRIPAP1 | c.1570_1582del p.W524Afs*2 | Frame Shift Del (DEL) | VAF 19/24 reads (79%) | called by mutect2, pindel, varscan2
- HACE1 | c.2282dup p.L761Ffs*17 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- IGHG4 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 146/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OXA1L | c.676del p.A226Qfs*23 (on ENST00000285848; = p.A166Qfs*23 on NM_005015.5) | Frame Shift Del (DEL) | VAF 137/458 reads (30%) | called by mutect2, pindel, varscan2
- PCGF1 | c.199+2_199+3del p.X67_splice | Splice Site (DEL) | VAF 21/60 reads (35%) | called by pindel, varscan2
- RETSAT | c.1231del p.Y411Tfs*50 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
- SEC23A | c.1909_1911del p.L637del | In Frame Del (DEL) | VAF 28/74 reads (38%) | called by pindel, varscan2
- SEL1L3 | c.2171_2174del p.T724Rfs*5 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | called by mutect2, pindel
- SRBD1 | c.395del p.K132Sfs*2 | Frame Shift Del (DEL) | VAF 20/188 reads (11%) | called by mutect2, varscan2
- UPF1 | c.1664_1671del p.L555Qfs*4 (on ENST00000599848 / NM_001297549.2; = p.L544Qfs*4 on NM_002911.4) | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- ACAN | c.2655G>A p.Q885= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100717371; called by muse, mutect2, varscan2
- ADA2 | c.1245G>A p.L415= (on ENST00000262607; = p.L174= on NM_177405.3) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99375812; called by muse, mutect2, varscan2
- ADCY8 | c.3540C>A p.I1180= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV99651187; called by muse, mutect2, varscan2
- AEBP1 | c.1665G>A p.V555= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99788537; called by muse, mutect2, varscan2
- AL136295.1 | c.1347C>T p.I449= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99937847; called by muse, mutect2, varscan2
- ANO10 | c.1107G>C p.V369= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV99428263; called by muse, mutect2, varscan2
- ARMC3 | c.2328G>C p.L776= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99957671; called by muse, mutect2, varscan2
- ARPP21 | c.45A>G p.G15= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99491344; called by muse, mutect2
- BTNL9 | c.69C>G p.L23= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100576111; called by muse, mutect2, varscan2
- C12orf50 | c.987G>A p.A329= | Silent (SNP) | VAF 81/171 reads (47%) | catalogued as rs762685869, COSV100072284, COSV53894688; called by muse, mutect2, varscan2
- CDH23 | c.8757C>T p.L2919= | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as rs973197490, COSV99819533; called by muse, mutect2, varscan2
- CNR1 | c.609C>T p.S203= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs976211578, COSV62987177; called by muse, mutect2
- COL27A1 | c.279C>G p.A93= | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as COSV100620797; called by muse, mutect2, varscan2
- CRLF3 | c.1059C>T p.C353= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV100158317; called by muse, mutect2, varscan2
- DNAJC13 | c.3906T>C p.A1302= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99606841; called by muse, mutect2, varscan2
- DYNC1I2 | c.1194G>C p.L398= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV99783713; called by muse, mutect2, varscan2
- ECE2 | c.102C>T p.G34= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs1040134230, COSV100668467; called by muse, mutect2, varscan2
- EYA4 | c.996C>T p.F332= (on ENST00000531901 / NM_001301013.1; = p.F326= on NM_004100.5) | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs773095472, CM138393, COSV62049831; called by muse, mutect2, varscan2
- GARNL3 | c.225A>T p.A75= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as COSV100150042; called by muse, mutect2, varscan2
- GCN1 | c.7930C>T p.L2644= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs1310502454, COSV100324791; called by muse, mutect2, varscan2
- GNAS | c.402C>T p.F134= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs771418632, COSV100005720; called by muse, mutect2, varscan2
- GUK1 | c.593G>A p.*198= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs768763694, COSV100451640; called by muse, mutect2, varscan2
- H2AC17 | c.156G>T p.L52= | Silent (SNP) | VAF 41/172 reads (24%) | catalogued as COSV100377519; called by muse, mutect2, varscan2
- HEATR4 | c.2820T>C p.V940= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV100407950; called by muse, mutect2, varscan2
- HEPACAM2 | c.450G>A p.V150= (on ENST00000394468 / NM_001039372.4; = p.V138= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100506415; called by muse, mutect2, varscan2
- INMT | c.612C>T p.Y204= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs779241370, COSV50001842, COSV99184967; called by muse, mutect2, varscan2
- INTS7 | c.2199A>G p.G733= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100877431; called by muse, mutect2, varscan2
- KHSRP | c.1962G>A p.K654= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101231151; called by muse, mutect2
- KIF6 | c.1248G>A p.A416= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs748097675, COSV54672814, COSV99760370; called by muse, mutect2, varscan2
- KLF5 | c.525G>A p.T175= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as COSV100890505; called by muse, mutect2, varscan2
- LAMB1 | c.4266G>A p.E1422= | Silent (SNP) | VAF 86/178 reads (48%) | catalogued as COSV99740187; called by muse, mutect2, varscan2
- LRRC37A3 | c.1131G>A p.P377= | Silent (SNP) | VAF 129/504 reads (26%) | catalogued as rs532383533, COSV59762551; called by muse, mutect2, varscan2
- LRRC66 | c.2610C>A p.A870= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100602860; called by muse, mutect2, varscan2
- MACROH2A2 | c.1008C>T p.A336= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV100325627; called by muse, mutect2, varscan2
- MPHOSPH9 | c.918A>G p.P306= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as COSV100186594; called by muse, mutect2, varscan2
- MUC5B | c.2694C>T p.Y898= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs546384509, COSV71591092; called by muse, mutect2, varscan2
- NME4 | c.435C>T p.I145= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1284842779, COSV99556732; called by muse, mutect2, varscan2
- NRXN1 | c.3456G>T p.L1152= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV58458273; called by muse, mutect2
- NUGGC | c.657G>A p.A219= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs372445724, COSV58434174; called by muse, mutect2, varscan2
- PARP6 | c.1290C>G p.V430= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99535880; called by muse, mutect2, varscan2
- PCDH19 | c.636C>T p.D212= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV55265938; called by muse, mutect2, varscan2
- PCDHGA3 | c.2121C>T p.F707= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as COSV54000338; called by muse, mutect2
- PDE6C | c.2355T>G p.T785= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101008611; called by muse, mutect2, varscan2
- PPP4R3B | c.1383A>G p.E461= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99701554; called by muse, mutect2, varscan2
- RAB11FIP1 | c.15C>G p.V5= | Silent (SNP) | VAF 30/216 reads (14%) | catalogued as COSV99769824; called by muse, mutect2, varscan2
- RNF150 | c.102C>T p.A34= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100153079; called by muse, mutect2, varscan2
- RSL1D1 | c.177T>C p.N59= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100851942; called by muse, mutect2, varscan2
- SCN11A | c.3531C>T p.A1177= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1360158947, COSV100181114; called by muse, mutect2, varscan2
- SDK1 | c.6087C>T p.L2029= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as rs1220245589, COSV67365295; called by muse, mutect2, varscan2
- SGCZ | c.795C>A p.S265= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV101171725, COSV66022045; called by muse, mutect2, varscan2
- SLITRK5 | c.774G>C p.L258= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100280486, COSV61526730; called by muse, mutect2, varscan2
- TENM3 | c.6606G>A p.T2202= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs140050384, COSV69298812; called by muse, mutect2, varscan2
- TLL1 | c.1188A>C p.L396= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV99286553; called by muse, mutect2, varscan2
- TRIM54 | c.717A>G p.Q239= (on ENST00000380075 / NM_187841.3; = p.Q281= on NM_032546.4) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99274222; called by muse, varscan2
- TTLL1 | c.1125C>T p.L375= | Silent (SNP) | VAF 24/249 reads (10%) | catalogued as rs373363791; called by muse, mutect2, varscan2
- UBQLNL | c.969C>A p.L323= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as COSV100974051; called by muse, mutect2, varscan2
- YY2 | c.126C>T p.Y42= | Silent (SNP) | VAF 49/57 reads (86%) | catalogued as COSV63412856; called by muse, mutect2, varscan2
- ZBTB20 | c.687G>T p.S229= (on ENST00000474710 / NM_001164342.2; = p.S156= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 56/93 reads (60%) | catalogued as COSV100613072, COSV61852489; called by muse, mutect2, varscan2
- ZBTB48 | c.699G>A p.V233= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV100039539; called by muse, mutect2, varscan2
- ZDBF2 | c.1704C>T p.T568= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as COSV65623681; called by muse, mutect2, varscan2
- ZFP69B | c.1197G>C p.A399= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100848214; called by mutect2, varscan2
- ZNF385D | c.207G>A p.G69= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV55756565; called by muse, mutect2, varscan2
- ADAM8 | c.*13G>A | 3'UTR (SNP) | VAF 18/50 reads (36%) | catalogued as rs545726760, COSV101291624; called by muse, mutect2, varscan2
- ARPP19P2 | n.330G>A | RNA (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3222+345G>C | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as rs755097663, COSV100208209; called by muse, mutect2, varscan2
- RFX7 | c.-151C>G | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100428365; called by muse, mutect2, varscan2
- UBTFL2 | n.492G>C | RNA (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
